Somatic mutation profile of tumor specimen TCGA-EJ-7328-01A (aliquot TCGA-EJ-7328-01A-31D-2114-08) from TCGA case TCGA-EJ-7328, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.5 years (25,756 days).
Specimen TCGA-EJ-7328-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e96c50e2-8c7d-4e15-8683-407a3c371094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7328-10A (Blood Derived Normal), aliquot TCGA-EJ-7328-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/492092d6-1da5-4417-8289-2d07cb9da724

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 21, Silent 11, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP4 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV54516702; called by muse, mutect2, varscan2
- ADGRL3 | c.1430T>A p.I477N (on ENST00000506720 / NM_001322402.2; = p.I409N on NM_015236.6) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV72267916; called by muse, mutect2, varscan2
- AKAP9 | c.5862C>T p.G1954= (on ENST00000359028; = p.G1922= on NM_005751.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/54 reads (20%) | catalogued as rs781051056, COSV62342079; called by muse, mutect2, varscan2
- ATG4A | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV57863636; called by muse, mutect2
- C3orf14 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV51706605; called by muse, mutect2, varscan2
- CCDC17 | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV59646780; called by muse, mutect2, varscan2
- GCNA | c.1539T>A p.N513K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as COSV65466470; called by muse, mutect2, varscan2
- GLDC | c.2613A>C p.K871N | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58678919; called by muse, mutect2, varscan2
- GPR17 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.006); catalogued as rs78078469; called by muse, mutect2, varscan2
- HECTD3 | c.1709T>G p.V570G | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV64669970; called by muse, mutect2, varscan2
- HKDC1 | c.1487A>G p.E496G | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV63576530; called by muse, mutect2
- JPH1 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV60610111; called by muse, mutect2, varscan2
- JPH4 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as rs374663076; called by muse, mutect2, varscan2
- LILRB5 | c.1525G>A p.G509S (on ENST00000449561 / NM_001081442.3; = p.G508S on NM_006840.5) | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV60256542; called by muse, mutect2, varscan2
- LRP2 | c.8657A>T p.E2886V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.438); catalogued as COSV55549199; called by muse, mutect2
- NEU1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.278); catalogued as rs145177628; called by muse, mutect2, varscan2
- PASD1 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs763797899, COSV100948982, COSV64854842; called by muse, mutect2, varscan2
- PLK3 | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59499599; called by muse, mutect2, varscan2
- PLPPR4 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64565354; called by muse, mutect2
- RXFP3 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs769916548, COSV100347748; called by muse, mutect2
- TRIM68 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs376554144; called by muse, mutect2, varscan2
- TRMT1 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53399946; called by muse, mutect2, varscan2
- ZNF485 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs372395438; called by muse, mutect2, varscan2
- BRCA2 | c.10088dup p.S3364Ifs*4 | Frame Shift Ins (INS) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- AGBL2 | c.1134G>A p.T378= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs370106534, COSV54089706; called by muse, mutect2, varscan2
- CACNA2D4 | c.420G>A p.A140= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs182825786, COSV54948219; called by muse, mutect2, varscan2
- FAT2 | c.9795C>T p.R3265= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV55817638; called by muse, mutect2
- FOXN3 | c.237G>A p.S79= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs764906969, COSV54305991; called by muse, mutect2, varscan2
- HNRNPF | c.831C>T p.G277= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs566452971, COSV61560873; called by muse, mutect2, varscan2
- IFIT5 | c.990C>T p.A330= | Silent (SNP) | VAF 40/240 reads (17%) | catalogued as COSV65655395; called by muse, mutect2, varscan2
- INTS14 | c.1350G>C p.L450= (on ENST00000313182 / NM_001366360.2; = p.L371= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV56011267; called by muse, mutect2, varscan2
- MUC16 | c.9120A>T p.T3040= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV67459243; called by muse, mutect2
- OR5F1 | c.438C>T p.A146= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs756447954, COSV53545224, COSV99558526; called by mutect2, varscan2
- PITX3 | c.906A>G p.V302= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1245162913, COSV64174299; called by muse, mutect2
- RB1 | c.963C>T p.Y321= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs377235036, CM034899, CM144779, COSV57297805; ClinVar: likely benign; called by muse, mutect2, varscan2
